Somatic mutation profile of tumor specimen 0DJC38 from CCDI case PBBWVA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Sex cord-gonadal stromal tumor, NOS; Tissue or organ of origin: Ovary; Age at diagnosis: 17.3 years (6,317 days).
Specimen 0DJC38: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37c39102-c528-4844-901f-d0d9ae453e6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJBLR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21131cea-e187-4a37-a7c6-2b67c04b7a80

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 2, Frame Shift Del 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5437G>A p.E1813K | Missense Mutation (SNP) | VAF 166/589 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as CM160050, COSV58615431, COSV58617855; called by muse, mutect2, varscan2
- DICER1 | c.4637dup p.Y1546* | Nonsense Mutation (INS) | VAF 142/515 reads (28%) | catalogued as rs1131691221; ClinVar: pathogenic; called by mutect2, varscan2
- ARMCX6 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 98/538 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV62680596; called by muse, mutect2, varscan2
- LAIR1 | c.734G>A p.S245N | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.234); catalogued as rs146736409; called by muse, mutect2, varscan2
- ADGB | c.3094C>G p.L1032V | Missense Mutation (SNP) | VAF 119/598 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ATP2B3 | c.1419C>A p.D473E | Missense Mutation (SNP) | VAF 140/451 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- HOXA2 | c.41G>C p.S14T | Missense Mutation (SNP) | VAF 125/689 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MTA3 | c.1634C>G p.P545R (on ENST00000405094 / NM_001330442.2; = p.P488R on NM_001282755.1) | Missense Mutation (SNP) | VAF 205/687 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MTSS1 | c.1680del p.M561Cfs*55 | Frame Shift Del (DEL) | VAF 68/385 reads (18%) | called by mutect2, varscan2
- PLXNB3 | c.2216C>T p.A739V | Missense Mutation (SNP) | VAF 83/315 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- U2AF1 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 81/268 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZNF449 | c.1114C>T p.L372F | Missense Mutation (SNP) | VAF 131/478 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- CD9 | c.622-41A>G | Intron (SNP) | VAF 62/262 reads (24%) | called by mutect2, varscan2
- DPEP3 | c.-45C>T | 5'UTR (SNP) | VAF 65/261 reads (25%) | catalogued as rs930671562; called by muse, mutect2, varscan2
- DST | c.21609+85A>G | Intron (SNP) | VAF 67/238 reads (28%) | called by muse, mutect2, varscan2
